Somatic mutation profile of tumor specimen TCGA-16-0848-01A (aliquot TCGA-16-0848-01A-01W-0424-08) from TCGA case TCGA-16-0848, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.1 years (20,848 days).
Specimen TCGA-16-0848-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea7fd4f3-a4df-4513-94c5-e54367a75dc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-0848-10A (Blood Derived Normal), aliquot TCGA-16-0848-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/192041a9-6ff6-4e10-94c8-12a31849a790

The open-access MAF lists 310 somatic variants for this specimen: 224 protein-altering or splice-affecting, 82 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 82, Frame Shift Ins 25, Nonsense Mutation 12, Intron 3, Frame Shift Del 3, Splice Site 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 10/83 reads (12%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- F9 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 76/109 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852233, CM940466, CM940467, CM960576, COSV54382023, COSV99496796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 151/328 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIGT | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 12/131 reads (9%) | catalogued as rs754517456, COSV99648814; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 139/272 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.8136dup p.D2713Rfs*10 | Frame Shift Ins (INS) | VAF 12/96 reads (13%) | catalogued as rs761483896; ClinVar: pathogenic; called by mutect2, pindel
- STAR | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs104894090, CM066240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 96/692 reads (14%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 318/427 reads (74%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs370246921, COSV99966651; called by muse, mutect2, varscan2
- ABCC10 | c.2263G>A p.A755T (on ENST00000372530 / NM_001198934.2; = p.A727T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as rs761988294, COSV99767937; called by muse, mutect2
- ABHD5 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs143489624; called by muse, mutect2, varscan2
- ABI2 | c.1399G>A p.E467K (on ENST00000295851 / NM_001375719.1; = p.E429K on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99652244; called by muse, mutect2, varscan2
- ACOX1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302158047, COSV53135864, COSV99503956; called by muse, mutect2, varscan2
- ACSS3 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567550679, COSV54098990; called by muse, mutect2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 15/92 reads (16%) | catalogued as rs767549806; called by mutect2, varscan2
- ADAMTSL1 | c.4123dup p.Q1375Pfs*53 | Frame Shift Ins (INS) | VAF 15/143 reads (10%) | catalogued as rs758913277; called by mutect2, varscan2
- ADCK2 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 29/175 reads (17%) | catalogued as rs919343786, COSV99301855; called by muse, mutect2, varscan2
- ADCY1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs768415059, COSV52029771; called by muse, mutect2, varscan2
- AGAP1 | c.2138G>A p.R713H (on ENST00000304032 / NM_001037131.3; = p.R660H on NM_014914.5) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs766895412, COSV58334446; called by muse, mutect2, varscan2
- AKAP13 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 136/296 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs774873759, COSV63473490; called by muse, mutect2, varscan2
- ANK2 | c.8728G>A p.V2910M | Missense Mutation (SNP) | VAF 95/459 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.251); catalogued as rs748400535, COSV100004068, COSV52170217; called by muse, mutect2, varscan2
- APAF1 | c.2207G>A p.R736Q (on ENST00000551964 / NM_181861.2; = p.R725Q on NM_001160.3) | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.049); catalogued as rs751875283, COSV59663045; called by muse, mutect2, varscan2
- APBA1 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454451021, COSV55237715, COSV99596318; called by muse, mutect2, varscan2
- APLP2 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 49/741 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.211); catalogued as rs371634970; called by muse, mutect2
- AREL1 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 127/755 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100707649; called by muse, mutect2, varscan2
- AREL1 | c.1101C>G p.F367L | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100707650; called by muse, mutect2, varscan2
- ARHGAP32 | c.4714G>A p.E1572K (on ENST00000310343 / NM_001378025.1; = p.E1223K on NM_014715.4) | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs200206728, COSV59843905; called by muse, mutect2, varscan2
- ASTN2 | c.3025C>T p.R1009C (on ENST00000313400 / NM_001365069.1; = p.R958C on NM_014010.5) | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs145202780, COSV56001308; called by muse, mutect2, varscan2
- ATP1A1 | c.2077A>G p.T693A | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99814758; called by muse, mutect2, varscan2
- B3GNTL1 | c.252dup p.H85Afs*7 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs755556988; called by pindel, varscan2
- BDKRB1 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as rs761261697, COSV53705645; called by muse, mutect2, varscan2
- BORCS5 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs757870676, COSV100056344, COSV53802857; called by muse, mutect2, varscan2
- BRMS1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751370154, COSV100240375; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 11/80 reads (14%) | catalogued as rs372345940; called by mutect2, varscan2
- CANT1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs886053526, COSV100185374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBLL1 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.448); catalogued as COSV99755909; called by muse, mutect2, varscan2
- CCDC142 | c.2203C>T p.R735C (on ENST00000393965 / NM_001365575.2; = p.R728C on NM_032779.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1349047936; called by muse, mutect2, varscan2
- CCDC80 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 630/1617 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs775543007, COSV52818945; called by muse, mutect2, varscan2
- CDH24 | c.714dup p.L239Afs*67 | Frame Shift Ins (INS) | VAF 10/53 reads (19%) | catalogued as rs765496989; called by mutect2, varscan2
- CENATAC | c.836dup p.D280Rfs*8 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | catalogued as rs1214317268; called by pindel, varscan2
- CEP131 | c.2072G>A p.R691H (on ENST00000269392 / NM_001319228.2; = p.R688H on NM_014984.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs752096772, COSV99488993; called by mutect2, varscan2
- CEP55 | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 73/106 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101017144; called by muse, mutect2, varscan2
- CEP63 | c.1151A>G p.H384R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs763437947, COSV100133091; called by muse, mutect2, varscan2
- CHKB | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1413704339, COSV100376829; called by muse, mutect2, varscan2
- CLDN4 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs368855545, COSV52897401; called by muse, mutect2, varscan2
- COL24A1 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs924339107, COSV100993956; called by muse, mutect2, varscan2
- CORIN | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs756151201, COSV56696840, COSV99904411; called by muse, mutect2, varscan2
- CPA5 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100812456; called by muse, mutect2, varscan2
- CRB2 | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777423121, COSV100749732; called by mutect2, varscan2
- CREB3L3 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs777963164, COSV50217377, COSV99314503; called by muse, mutect2, varscan2
- CSMD2 | c.7384C>T p.R2462C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs938410594, COSV53978139; called by muse, mutect2, varscan2
- CSMD2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs761180145, COSV53892340; called by muse, mutect2, varscan2
- CTDSP1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99812085; called by muse, mutect2, varscan2
- CYP2B6 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs752695347, COSV57844965; called by muse, mutect2
- DENND2B | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1287941055, COSV100567819; called by muse, mutect2, varscan2
- DHX35 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 109/368 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376209770; called by muse, mutect2, varscan2
- DIS3L | c.962C>T p.S321L (on ENST00000319212 / NM_001143688.3; = p.S238L on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs144553500; called by muse, mutect2, varscan2
- DNAAF5 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as rs200034358, COSV52414600, COSV99860278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMBP | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV100144385; called by muse, mutect2, varscan2
- DNTT | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779136442, COSV100960684, COSV64523888; called by muse, mutect2, varscan2
- DPP4 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149643982, COSV62106254; called by muse, mutect2, varscan2
- DST | c.18574G>A p.E6192K (on ENST00000361203 / NM_001374722.1; = p.E3889K on NM_015548.5) | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.847); catalogued as rs756660501, COSV54999095; called by muse, mutect2, varscan2
- E2F2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 211/933 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419056781, COSV62276348; called by muse, varscan2
- EBF1 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs778162720, COSV58180087; called by muse, mutect2
- ELMOD3 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100226479, COSV59772880; called by muse, mutect2, varscan2
- ETAA1 | c.1906A>T p.I636L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99712934; called by muse, varscan2
- EXTL3 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 76/531 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as rs141948891; called by muse, mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 76/562 reads (14%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FCGBP | c.12046C>T p.R4016C | Missense Mutation (SNP) | VAF 231/345 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs1460438828; called by muse, mutect2, varscan2
- FHOD3 | c.3025G>A p.D1009N (on ENST00000359247 / NM_001281739.3; = p.D1026N on NM_025135.5) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs554487359, COSV57165602, COSV99941725; called by muse, mutect2, varscan2
- FLOT1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52544455; called by muse, mutect2, varscan2
- FRMPD4 | c.3874C>T p.P1292S | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.859); catalogued as rs780443219, COSV101044011; called by muse, mutect2, varscan2
- FTSJ1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs76994219, COSV99191451; called by muse, mutect2, varscan2
- FYCO1 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs149818406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAD1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.149); catalogued as COSV60151756; called by muse, mutect2, varscan2
- GBP3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 157/255 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs145016759; called by muse, mutect2, varscan2
- GBX2 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs61743573, COSV100103611; called by mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 29/236 reads (12%) | catalogued as rs768450027; called by mutect2, varscan2
- GGNBP2 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs201874238; called by muse, mutect2, varscan2
- GGT1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs113647199, COSV50646320; called by muse, mutect2, varscan2
- GLI1 | c.821dup p.C275Lfs*32 | Frame Shift Ins (INS) | VAF 39/314 reads (12%) | catalogued as rs759448855; called by mutect2, varscan2
- GPATCH8 | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 54/720 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); catalogued as rs749352671, COSV59193364; called by muse, mutect2
- GPLD1 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs978168751, COSV57755613; called by muse, mutect2, varscan2
- GRIN2B | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 59/563 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1428234478, COSV74204916; called by muse, mutect2, varscan2
- GRIP1 | c.2906G>A p.R969Q (on ENST00000359742 / NM_001379345.1; = p.R917Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.394); catalogued as rs781673053, COSV99670915; called by muse, mutect2
- H1-3 | c.52A>G p.T18A | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1225421203, COSV99768886; called by muse, mutect2, varscan2
- HIP1 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 20/805 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373608095, COSV61187980; called by muse, mutect2
- HTRA4 | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100205939; called by muse, mutect2, varscan2
- IFI16 | c.1825G>T p.E609* (on ENST00000295809 / NM_001364867.2; = p.E553* on NM_005531.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/154 reads (39%) | catalogued as COSV99858141; called by muse, mutect2, varscan2
- IGHMBP2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769046350, COSV99662537, COSV99662681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ILK | c.172dup p.A58Gfs*11 | Frame Shift Ins (INS) | VAF 16/137 reads (12%) | catalogued as rs770182262; called by mutect2, pindel, varscan2
- ITGA8 | c.1970+1G>A p.X657_splice | Splice Site (SNP) | VAF 76/130 reads (58%) | catalogued as rs749220565, COSV100959707; called by muse, mutect2, varscan2
- ITGAE | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 76/1070 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs747958723, COSV99561512; called by muse, mutect2
- KCNAB1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV67484538; called by muse, mutect2, varscan2
- KCNB1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1338339252, COSV65568401; called by muse, mutect2, varscan2
- KCNJ11 | c.334A>C p.T112P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV100379219; called by muse, mutect2
- KCNQ3 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 117/557 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753513804, COSV101196417; called by muse, mutect2, varscan2
- KCNQ4 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs761479115, COSV100714415; called by muse, mutect2, varscan2
- KCNS3 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 16/353 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100411436; called by muse, mutect2
- KDM4B | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 171/659 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50209005; called by muse, mutect2, varscan2
- KLHL18 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 61/570 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1171041482, COSV99231275; called by muse, mutect2, varscan2
- KLHL32 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1469633500, COSV100987486; called by muse, mutect2, varscan2
- L1CAM | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 180/217 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs201311640, CM151720, COSV100649453; called by muse, mutect2, varscan2
- LAX1 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 100/947 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV100920094; called by muse, mutect2, varscan2
- LILRB4 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs766142180, COSV54408647, COSV99553791; called by muse, mutect2
- LPCAT1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as rs1339369321, COSV99359340; called by muse, mutect2, varscan2
- LPO | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1442109405, COSV99229358; called by muse, mutect2, varscan2
- LRCH3 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 45/156 reads (29%) | catalogued as rs754999037, COSV100605081; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 24/125 reads (19%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP2 | c.13754G>A p.R4585Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs764511347, COSV55540466; called by muse, mutect2, varscan2
- MADD | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 37/696 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.747); catalogued as rs745443979, COSV100211940; called by muse, mutect2
- MAP3K15 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 159/206 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs766154880, COSV58830904, COSV58839303; called by muse, mutect2, varscan2
- MARCHF2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as rs763102811, COSV99294889; called by muse, mutect2, varscan2
- MAT2A | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52087194; called by muse, mutect2, varscan2
- MCM3AP | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 160/309 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99387481; called by muse, mutect2, varscan2
- MCRS1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs746343401, COSV57792538; called by muse, mutect2, varscan2
- MECR | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 28/483 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs759114736, COSV99747397; called by muse, mutect2
- MLH1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 86/968 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs754554026, COSV51613926; ClinVar: uncertain significance; called by muse, mutect2
- MMP15 | c.1650G>T p.K550N | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99539718; called by muse, mutect2, varscan2
- MOGS | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs752641712, COSV51968934; ClinVar: uncertain significance; called by mutect2, varscan2
- MORN3 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 201/414 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs747756614, COSV62507817; called by muse, mutect2, varscan2
- MRE11 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 91/322 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs587781378, COSV100120030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSH6 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 122/314 reads (39%) | catalogued as rs747477669, COSV99316899; called by muse, mutect2, varscan2
- MYH3 | c.5648C>T p.A1883V | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs770070846, COSV56866464; called by muse, mutect2, varscan2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 34/240 reads (14%) | catalogued as rs761123152; called by mutect2, varscan2
- NPAS4 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs1210527164; called by muse, mutect2
- NTN4 | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as rs1403390954, COSV59224570; called by muse, mutect2, varscan2
- NUAK1 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV99776678; called by muse, mutect2
- NUP205 | c.2626G>C p.V876L | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.362); catalogued as COSV53664641, COSV99607560; called by muse, mutect2
- OBSCN | c.18482G>A p.R6161H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs546819825; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 34/304 reads (11%) | catalogued as rs780916980; called by mutect2, varscan2
- OTX2 | c.106C>T p.R36W (on ENST00000408990 / NM_172337.3; = p.R44W on NM_021728.4) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD124838, COSV100258088; called by muse, mutect2, varscan2
- PAK5 | c.2060A>G p.Q687R | Missense Mutation (SNP) | VAF 141/287 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100781661; called by muse, mutect2, varscan2
- PARP1 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 124/896 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs759579130, COSV100829045; called by muse, varscan2
- PCDHB5 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV50651091; called by muse, mutect2, varscan2
- PCDHGC3 | c.2050dup p.R684Pfs*41 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs764598056; called by pindel, varscan2
- PGPEP1 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.266); catalogued as rs201898854, COSV99416408, COSV99416696; called by muse, mutect2, varscan2
- PHACTR1 | c.759dup p.P254Afs*78 | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | catalogued as rs749326031; called by mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 47/328 reads (14%) | catalogued as rs749506841; called by mutect2, varscan2
- PIK3R6 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100266850; called by muse, mutect2, varscan2
- POLR2E | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142308779; called by mutect2, varscan2
- PPFIA3 | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99418305; called by muse, mutect2, varscan2
- PPP4R4 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs1006379723, COSV58553766; called by muse, mutect2, varscan2
- PRG4 | c.3917G>A p.R1306H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1557970634, COSV100798311; called by muse, mutect2, varscan2
- PRICKLE2 | c.1790G>A p.R597Q (on ENST00000295902; = p.R541Q on NM_198859.4) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs768214855, COSV55765700; called by muse, mutect2, varscan2
- PSG6 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 21/437 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51829705, COSV99414507; called by muse, mutect2
- PTGER3 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs777755530, COSV60690336; called by muse, mutect2, varscan2
- PTPN13 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 31/610 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.121); catalogued as rs151160491; called by muse, mutect2
- PYCR2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs754486659; called by muse, mutect2, varscan2
- QTRT1 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754147172, COSV99139112; called by muse, mutect2, varscan2
- RAD54B | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs746694103, COSV60250792; called by muse, mutect2, varscan2
- RAD54L | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs147366486; called by muse, mutect2, varscan2
- RESF1 | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as rs763753313, COSV57019973; called by muse, mutect2, varscan2
- RFC2 | c.1057G>A p.A353T (on ENST00000055077 / NM_181471.3; = p.A319T on NM_002914.4) | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV50017273; called by muse, mutect2
- RFTN2 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs757592246, COSV54388942; called by muse, mutect2, varscan2
- RGPD1 | c.4067G>A p.G1356D (on ENST00000409776; = p.G1364D on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as COSV101233692; called by muse, mutect2, varscan2
- RIF1 | c.4331G>A p.R1444H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs765365931, COSV99691211; called by muse, mutect2, varscan2
- RNF220 | c.1475T>C p.F492S | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100132257; called by muse, mutect2, varscan2
- ROCK2 | c.3638A>T p.Q1213L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100255913; called by muse, mutect2, varscan2
- RRNAD1 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748934059, COSV100836998; called by muse, mutect2, varscan2
- RTN3 | c.2290C>T p.R764C (on ENST00000377819 / NM_001265589.2; = p.R745C on NM_201428.3) | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs147247159; called by muse, mutect2, varscan2
- SBF1 | c.3228dup p.S1077Qfs*11 | Frame Shift Ins (INS) | VAF 20/152 reads (13%) | catalogued as rs771002611; called by mutect2, varscan2
- SCML1 | c.643C>T p.R215W (on ENST00000380041 / NM_001037540.3; = p.R188W on NM_006746.6) | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101193977; called by muse, mutect2, varscan2
- SCRIB | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs866306647, COSV57593182; called by muse, varscan2
- SDS | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs1199824791, COSV55109071; called by muse, mutect2
- SEC24C | c.1375dup p.Q459Pfs*17 | Frame Shift Ins (INS) | VAF 80/741 reads (11%) | catalogued as rs764652839; called by mutect2, varscan2
- SESTD1 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs749484642, COSV100090882; called by muse, varscan2
- SETD7 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV56800224; called by muse, mutect2, varscan2
- SLC14A2 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs1462386004, COSV54910627; called by muse, mutect2, varscan2
- SLC22A13 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs144451006, COSV61291789; called by muse, varscan2
- SLC2A1 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 144/401 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1387242348, CM118205, COSV100995962; called by muse, mutect2, varscan2
- SLC38A11 | c.290G>A p.R97H (on ENST00000409149 / NM_001351539.1; = p.R75H on NM_173512.2) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs914142729, COSV58053143; called by muse, varscan2
- SLC39A9 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.708); catalogued as rs376565540, COSV99220693; called by muse, mutect2, varscan2
- SLC5A12 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54821476; called by muse, mutect2, varscan2
- SMOX | c.908dup p.R304Qfs*4 | Frame Shift Ins (INS) | VAF 9/55 reads (16%) | catalogued as rs746816975; called by mutect2, varscan2
- SPDYE5 | c.404dup p.H136Afs*2 | Frame Shift Ins (INS) | VAF 16/155 reads (10%) | catalogued as rs782801833; called by mutect2, pindel
- SPEN | c.5749C>T p.R1917C | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1298127512, COSV65357260; called by muse, mutect2, varscan2
- SPTA1 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 49/100 reads (49%) | catalogued as COSV100935524; called by muse, mutect2, varscan2
- SREBF2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.526); catalogued as COSV100761547; called by muse, mutect2, varscan2
- STAG1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs749698375, COSV99366878; called by muse, mutect2, varscan2
- SUPT6H | c.2984G>A p.R995Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379806291, COSV100112687, COSV58928187; called by muse, mutect2, varscan2
- SV2C | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs759085527, COSV59227182; called by muse, mutect2, varscan2
- SYNPO2 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs918346408, COSV100206350; called by muse, mutect2, varscan2
- TAP2 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 65/148 reads (44%) | catalogued as rs771932254, HM0717, COSV66498536; called by muse, mutect2, varscan2
- TCEAL6 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.933); catalogued as rs781896186, COSV101036037; called by muse, mutect2
- TGFBRAP1 | c.2173C>T p.H725Y | Missense Mutation (SNP) | VAF 4/6 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV99305509; called by mutect2, varscan2
- THAP11 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99534593; called by muse, mutect2, varscan2
- TKT | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 84/692 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); catalogued as rs782692158, COSV99965151; called by muse, mutect2
- TRAPPC5 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs774090407, COSV58039412, COSV58040334; called by muse, mutect2, varscan2
- TTC37 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as rs1352204815, COSV62456939; called by muse, mutect2, varscan2
- TTN | c.58406C>T p.A19469V (on ENST00000591111; = p.A12045V on NM_003319.4) | Missense Mutation (SNP) | VAF 145/457 reads (32%) | PolyPhen benign (0.035); catalogued as rs370687831; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- TUT1 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99545579; called by muse, mutect2, varscan2
- TYR | c.740G>A p.C247Y | Missense Mutation (SNP) | VAF 132/1874 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99635263; called by muse, mutect2
- UBR2 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100867518; called by muse, varscan2
- UNC79 | c.6757C>T p.R2253* (on ENST00000393151 / NM_001346218.2; = p.R2076* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 63/202 reads (31%) | catalogued as COSV56383345; called by muse, mutect2, varscan2
- VILL | c.1438dup p.H480Pfs*38 | Frame Shift Ins (INS) | VAF 10/66 reads (15%) | catalogued as rs753585188; called by mutect2, varscan2
- WDR6 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs762832120, COSV100556705; called by muse, mutect2, varscan2
- WDR83 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs759704090, COSV99269752; called by muse, mutect2, varscan2
- XRCC6 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 111/373 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV100777913; called by muse, mutect2, varscan2
- YLPM1 | c.5209C>T p.R1737C | Missense Mutation (SNP) | VAF 60/586 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753719257; called by muse, mutect2, varscan2
- ZDHHC18 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1198469791, COSV100938871; called by muse, mutect2, varscan2
- ZNF101 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 97/354 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs753717367, COSV58908780; called by muse, mutect2, varscan2
- ZNF490 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.486); catalogued as rs773377509, COSV61007592; called by muse, mutect2, varscan2
- ZNF584 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 71/607 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs531074344, COSV100183414; called by muse, mutect2, varscan2
- ZNF644 | c.2518G>A p.V840I | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs267598765, COSV61347327; called by muse, mutect2, varscan2
- ZNF804B | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs781202005, COSV60814724; called by muse, mutect2, varscan2
- ADAMTS6 | c.3083_3087+21del p.X1028_splice | Splice Site (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- ADH5 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 17/250 reads (7%) | called by muse, mutect2
- BCL11A | c.994G>A p.A332T (on ENST00000335712 / NM_001365609.1; = p.A366T on NM_018014.4) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CAMTA1 | c.3728C>T p.P1243L | Missense Mutation (SNP) | VAF 48/665 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); called by muse, mutect2
- CNTN1 | c.1511C>G p.P504R | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2
- EFTUD2 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- H2AC17 | c.227del p.K76Rfs*58 | Frame Shift Del (DEL) | VAF 77/244 reads (32%) | called by mutect2, pindel, varscan2
- MTMR7 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 34/874 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- MYH6 | c.3105+1G>A p.X1035_splice | Splice Site (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- NXN | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCMTD2 | c.697G>T p.V233F | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- PHEX | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2
- RNF39 | c.664del p.M222Cfs*5 | Frame Shift Del (DEL) | VAF 77/837 reads (9%) | called by mutect2, pindel
- SLC9B1 | c.331del p.I111Ffs*9 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, varscan2
- SYNGAP1 | c.3640C>T p.R1214W | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TSPYL6 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VWA7 | c.1163dup p.G389Wfs*5 | Frame Shift Ins (INS) | VAF 13/142 reads (9%) | called by mutect2, pindel
- ABCA2 | c.1935C>T p.D645= (on ENST00000614293; = p.D615= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs563442914, COSV99688398; called by mutect2, varscan2
- ADGRA1 | c.120C>T p.I40= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs751844986, COSV66930793; called by muse, mutect2, varscan2
- ADGRG4 | c.507C>T p.S169= | Silent (SNP) | VAF 18/495 reads (4%) | catalogued as rs1179178286, COSV54966936; called by muse, mutect2
- BIVM-ERCC5 | c.3273C>T p.A1091= | Silent (SNP) | VAF 77/275 reads (28%) | catalogued as rs569227686, COSV100863929; ClinVar: likely benign; called by muse, mutect2, varscan2
- BTNL8 | c.105C>T p.D35= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs371053690; called by muse, mutect2, varscan2
- C8G | c.381C>T p.V127= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs141247513; called by muse, mutect2, varscan2
- CCN2 | c.561G>A p.T187= | Silent (SNP) | VAF 4/61 reads (7%) | catalogued as rs940201069, COSV100915360; called by muse, mutect2
- CDH5 | c.2328G>A p.S776= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV58517896; called by muse, mutect2, varscan2
- CECR2 | c.2376C>T p.A792= (on ENST00000342247 / NM_001290047.2; = p.A609= on NM_001290046.1) | Silent (SNP) | VAF 63/210 reads (30%) | catalogued as rs775554817, COSV52838649, COSV99379056; called by muse, mutect2, varscan2
- CETN1 | c.282G>A p.T94= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV59121212; called by mutect2, varscan2
- CHAF1B | c.690C>T p.D230= | Silent (SNP) | VAF 102/357 reads (29%) | catalogued as rs373907249; called by muse, mutect2, varscan2
- CNGA3 | c.1404C>T p.I468= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1465351825, COSV55628623; called by muse, mutect2, varscan2
- CNGB3 | c.768G>A p.A256= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as rs767128005, COSV60689772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.2856C>T p.F952= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as rs747574881, COSV64625998; ClinVar: likely benign; called by muse, mutect2, varscan2
- CORO2B | c.177C>T p.S59= | Silent (SNP) | VAF 53/80 reads (66%) | catalogued as rs542742755, COSV55953636; called by muse, mutect2, varscan2
- DDX41 | c.708G>A p.T236= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as rs920310571, COSV100286820; called by muse, mutect2, varscan2
- DPAGT1 | c.435C>A p.G145= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- ESPL1 | c.2101C>A p.R701= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- FGL2 | c.1117C>T p.L373= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- FO393400.1 | c.282G>A p.A94= | Silent (SNP) | VAF 84/202 reads (42%) | catalogued as rs764422132, COSV54071718; called by muse, mutect2, varscan2
- FOXO3 | c.1023G>A p.A341= | Silent (SNP) | VAF 193/408 reads (47%) | catalogued as rs370562790; called by muse, mutect2, varscan2
- FSIP2 | c.19458T>C p.N6486= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs776555925, COSV100556399; called by muse, mutect2, varscan2
- GALNT10 | c.1203C>T p.Y401= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs557019914, COSV51728790; called by muse, mutect2, varscan2
- GALNT15 | c.837C>T p.L279= | Silent (SNP) | VAF 65/174 reads (37%) | catalogued as rs374048513; called by muse, mutect2, varscan2
- GIT2 | c.312G>A p.A104= | Silent (SNP) | VAF 237/619 reads (38%) | catalogued as rs370200013; called by muse, mutect2, varscan2
- GON4L | c.555C>A p.G185= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as rs955372115; called by muse, mutect2
- GRWD1 | c.978C>T p.G326= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs763482368, COSV53517736; called by mutect2, varscan2
- HCST | c.213C>T p.C71= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- HECW2 | c.681C>T p.H227= | Silent (SNP) | VAF 62/188 reads (33%) | catalogued as rs760309516, COSV99647110, COSV99648899; called by muse, mutect2, varscan2
- HMCN1 | c.15585A>G p.E5195= | Silent (SNP) | VAF 91/345 reads (26%) | catalogued as COSV99635308; called by muse, mutect2, varscan2
- HSPG2 | c.2361G>A p.T787= | Silent (SNP) | VAF 78/257 reads (30%) | catalogued as rs750614056, COSV101021189; called by muse, mutect2, varscan2
- IL20RB | c.177G>A p.A59= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs959336573, COSV100291273; called by muse, mutect2, varscan2
- IL3RA | c.57G>A p.T19= | Silent (SNP) | VAF 337/1174 reads (29%) | catalogued as rs779974164, COSV100452385; called by muse, mutect2, varscan2
- ITSN2 | c.666G>A p.S222= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs778654550, COSV100744134; called by muse, mutect2
- KALRN | c.3414C>T p.S1138= | Silent (SNP) | VAF 66/187 reads (35%) | catalogued as rs781542196, COSV53781262, COSV99567171; called by muse, mutect2
- KMT2B | c.3723C>T p.H1241= | Silent (SNP) | VAF 70/209 reads (33%) | catalogued as rs762663354, COSV99720583; called by muse, mutect2, varscan2
- KSR2 | c.2100C>T p.N700= | Silent (SNP) | VAF 36/462 reads (8%) | catalogued as rs781403631, COSV56671853, COSV56674291; called by muse, mutect2
- LRRC25 | c.90G>A p.A30= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100170607; called by muse, mutect2, varscan2
- MAN1C1 | c.1467C>T p.Y489= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs944298097, COSV99848917; called by muse, mutect2, varscan2
- MPPE1 | c.1020G>A p.T340= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as rs558317965, COSV52327051; called by muse, mutect2, varscan2
- MRGPRX4 | c.135C>T p.N45= | Silent (SNP) | VAF 54/87 reads (62%) | catalogued as rs746707315, COSV100049842; called by muse, mutect2, varscan2
- MSANTD1 | c.351C>T p.S117= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs776594697, COSV101433676; called by muse, mutect2, varscan2
- MTA1 | c.849C>T p.D283= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs782204369, COSV58759514; called by muse, mutect2, varscan2
- MTARC1 | c.870G>A p.P290= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs374227225, COSV65055600; called by muse, mutect2, varscan2
- MYBPC1 | c.57G>A p.P19= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs772946518, COSV100638254; called by muse, mutect2, varscan2
- MYH6 | c.3894G>A p.A1298= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs151135141; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYOZ1 | c.444G>A p.A148= | Silent (SNP) | VAF 42/68 reads (62%) | catalogued as rs779906026, COSV63772633; called by muse, mutect2, varscan2
- NAT9 | c.372C>T p.A124= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs555556955, COSV52853491; called by muse, mutect2
- NDRG1 | c.303C>T p.D101= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs765528167, COSV100106429, COSV60484006; ClinVar: likely benign; called by muse, mutect2, varscan2
- NDUFS7 | c.399G>A p.A133= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs144868423; called by muse, mutect2
- NFATC1 | c.702G>A p.P234= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs754626986, COSV99502485; called by muse, mutect2, varscan2
- NRSN2 | c.39C>T p.R13= | Silent (SNP) | VAF 73/139 reads (53%) | catalogued as rs368963058; called by muse, mutect2, varscan2
- OBSCN | c.7119C>T p.F2373= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs745471202, COSV99483982; called by muse, mutect2, varscan2
- OPN5 | c.636G>A p.T212= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV99790030; called by muse, mutect2, varscan2
- OR10H5 | c.24C>T p.S8= | Silent (SNP) | VAF 199/1020 reads (20%) | catalogued as rs776309210, COSV58279465; called by muse, mutect2, varscan2
- PACSIN1 | c.981G>A p.A327= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs1490939597, COSV55058923; called by muse, mutect2, varscan2
- PCDHA1 | c.300G>A p.A100= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100974462; called by muse, varscan2
- PLEKHG6 | c.777C>A p.P259= | Silent (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- PTCH2 | c.2811C>T p.A937= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs375965470; called by mutect2, varscan2
- RANBP10 | c.795C>T p.L265= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs767427091, COSV100449474; called by mutect2, varscan2
- RPN2 | c.675G>A p.E225= | Silent (SNP) | VAF 30/471 reads (6%) | catalogued as rs369006724; called by muse, mutect2
- RPS6KL1 | c.1386G>A p.T462= | Silent (SNP) | VAF 51/88 reads (58%) | catalogued as rs774897997, COSV100665214; called by muse, mutect2, varscan2
- SAXO2 | c.1131C>T p.F377= | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as rs762093678, COSV100255905; called by muse, mutect2, varscan2
- SFXN1 | c.123C>T p.N41= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs376235466; called by muse, mutect2, varscan2
- SLC25A48 | c.597C>T p.Y199= (on ENST00000650267; = p.Y145= on NM_001349335.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs746489691, COSV50853058; called by muse, mutect2, varscan2
- SLCO3A1 | c.1791C>T p.I597= | Silent (SNP) | VAF 57/197 reads (29%) | catalogued as rs150046342; called by muse, mutect2, varscan2
- SNX8 | c.741C>T p.I247= | Silent (SNP) | VAF 165/520 reads (32%) | catalogued as rs747318950, COSV56126363; called by muse, mutect2, varscan2
- SPG21 | c.873C>T p.A291= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99200206; called by muse, mutect2, varscan2
- SRP72 | c.132C>T p.D44= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs530644774, COSV100714375, COSV61379184; called by muse, mutect2, varscan2
- STYXL2 | c.1386C>T p.H462= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs1318279497, COSV99608846; called by muse, mutect2, varscan2
- SV2A | c.1473C>T p.R491= | Silent (SNP) | VAF 93/245 reads (38%) | catalogued as rs782094239, COSV64965958; called by muse, mutect2, varscan2
- TANC1 | c.1422C>T p.S474= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV55083018; called by muse, mutect2, varscan2
- TIAM1 | c.405C>T p.Y135= | Silent (SNP) | VAF 155/521 reads (30%) | catalogued as rs151048315, COSV54554850, COSV54558965; called by muse, mutect2, varscan2
- TOX | c.678C>T p.G226= | Silent (SNP) | VAF 98/1396 reads (7%) | catalogued as rs531597509, COSV100812798; called by muse, mutect2
- TRRAP | c.1386C>T p.Y462= | Silent (SNP) | VAF 18/543 reads (3%) | catalogued as COSV100722913; called by muse, mutect2
- TTC21A | c.738C>T p.S246= | Silent (SNP) | VAF 30/162 reads (19%) | catalogued as COSV100087650; called by mutect2, varscan2
- UBE3C | c.1293G>A p.T431= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs990859814, COSV100780079; called by muse, mutect2, varscan2
- WDPCP | c.738C>T p.N246= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs543308588, COSV55431676; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZBTB20 | c.2100C>T p.R700= (on ENST00000474710 / NM_001164342.2; = p.R627= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs772866543, COSV100615145; called by muse, mutect2, varscan2
- ZNF605 | c.1692C>T p.S564= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs746347356, COSV59159384; called by muse, mutect2, varscan2
- ZNF626 | c.483C>T p.N161= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs567636048, COSV74129659; called by muse, mutect2
- ZNF76 | c.348G>A p.E116= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1379950038, COSV57591335; called by muse, mutect2, varscan2
- DNAJC5 | c.-11-8852C>T | Intron (SNP) | VAF 30/38 reads (79%) | catalogued as rs756328807, COSV62670691; called by muse, varscan2
- MELTF | c.712+1677C>T | Intron (SNP) | VAF 87/197 reads (44%) | catalogued as rs756325952, COSV56384045, COSV99585970; called by muse, mutect2, varscan2
- PAX3 | chr2:222201413 C>T | 3'Flank (SNP) | VAF 182/455 reads (40%) | catalogued as rs753282124, COSV60590085; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3354dup | Intron (INS) | VAF 12/64 reads (19%) | catalogued as rs767992187; called by mutect2, varscan2
